Somatic mutation profile of tumor specimen HTMCP-03-06-02137-01A (aliquot HTMCP-03-06-02137-01A-01D-5099) from CGCI case HTMCP-03-06-02137, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G3.
Specimen HTMCP-03-06-02137-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa2bdaa5-0df2-4268-a08b-b0d6d91a1b20.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02137-10A (Blood Derived Normal), aliquot HTMCP-03-06-02137-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06014474-44b5-4a4e-a31a-8e6185f6cda4

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 4, Splice Region 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 41/86 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ASTN1 | c.3733C>T p.R1245C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.988); catalogued as rs754478022, COSV100707640; called by muse, mutect2, varscan2
- CACNA1G | c.5781G>A p.T1927= | Splice Region (SNP) | VAF 6/26 reads (23%) | catalogued as rs758628716, COSV61731971; called by muse, varscan2
- CARMIL3 | c.2000C>T p.T667M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs1037045171; called by muse, mutect2, varscan2
- CBFB | c.165+1G>T p.X55_splice | Splice Site (SNP) | VAF 5/12 reads (42%) | catalogued as COSV51996680, COSV51997241, COSV51997594, COSV52002060; called by muse, mutect2, varscan2
- CD47 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 57/278 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1218151856, COSV100790136; called by muse, mutect2, varscan2
- CDHR2 | c.3048C>A p.Y1016* | Nonsense Mutation (SNP) | VAF 15/49 reads (31%) | catalogued as COSV99991117; called by muse, mutect2, varscan2
- CFAP74 | c.2813C>T p.T938M | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as rs976978756; called by muse, mutect2, varscan2
- DMD | c.4000G>A p.G1334R | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs146880270, COSV63780212; called by muse, mutect2, varscan2
- PALM3 | c.1828G>A p.A610T (on ENST00000340790; = p.A625T on NM_001145028.2) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.133); catalogued as rs1242787562; called by muse, mutect2, varscan2
- PCDHA2 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.279); catalogued as rs1355078220, COSV65369345; called by muse, mutect2, varscan2
- PLXNB2 | c.5060G>A p.R1687Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100833917, COSV63782491; called by muse, mutect2, varscan2
- SLC29A4 | c.472C>T p.Q158* | Nonsense Mutation (SNP) | VAF 17/29 reads (59%) | catalogued as rs758793681; called by muse, mutect2, varscan2
- STAG2 | c.1840C>T p.R614* | Nonsense Mutation (SNP) | VAF 22/32 reads (69%) | catalogued as CM157403, COSV54351398; called by muse, mutect2, varscan2
- ZNF551 | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 123/285 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as rs750182389, COSV99989822; called by muse, mutect2, varscan2
- BCORL1 | c.2242C>T p.Q748* | Nonsense Mutation (SNP) | VAF 37/42 reads (88%) | called by muse, mutect2, varscan2
- CCDC183 | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD47 | c.909G>A p.R303= | Splice Region (SNP) | VAF 39/204 reads (19%) | called by muse, mutect2, varscan2
- GNA11 | c.461C>G p.S154C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NSD2 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- TEX14 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- TNKS2 | c.3311G>T p.G1104V | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UNC79 | c.4693C>T p.P1565S (on ENST00000393151 / NM_001346218.2; = p.P1388S on NM_020818.5) | Missense Mutation (SNP) | VAF 68/134 reads (51%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZNF599 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 22/136 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP14 | c.327C>T p.F109= | Silent (SNP) | VAF 24/85 reads (28%) | catalogued as rs549293146, COSV55664734; called by muse, mutect2, varscan2
- CFAP46 | c.2373G>A p.A791= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs555094750; called by muse, mutect2, varscan2
- OTOGL | c.5895T>C p.C1965= (on ENST00000547103; = p.C1956= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/132 reads (35%) | called by muse, mutect2, varscan2
- RC3H2 | c.2031G>A p.P677= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as rs563442324, COSV100605385, COSV61802129; called by muse, mutect2, varscan2
- TNKS2 | c.3312A>T p.G1104= | Silent (SNP) | VAF 35/96 reads (36%) | called by muse, mutect2, varscan2
- VPS13C | c.11016A>G p.P3672= (on ENST00000644861 / NM_020821.3; = p.P3629= on NM_017684.5) | Silent (SNP) | VAF 137/300 reads (46%) | called by muse, mutect2, varscan2
